Gene-level copy-number profile of specimen HCM-BROD-0870-C43-85N from HCMI case HCM-BROD-0870-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.3 years (18,388 days).
Specimen HCM-BROD-0870-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce9ee037-f475-41a9-b1a7-484485ea60d1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0870-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ccc1a976-1216-46f6-90f2-eca06d81d7eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 683; copy number 2: 57,611; copy number 3: 16; copy number 4: 8; copy number 5: 1; copy number 6: 1; copy number 9: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,506,022, 1 gene: ANKRD20A17P.
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr7:94,278,680–94,431,227, 2 genes: AC002074.1, COL1A2.
- chr9:67,832,765–68,531,061, 12 genes (within-gene range 0–4): ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr11:89,924,064–89,980,661, 7 genes: TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7.
- chr14:18,333,726–18,633,634, 12 genes (within-gene range 0–2): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297.
- chr14:18,634,955–18,637,421, 2 genes (within-gene range 0–2): CR383656.1, CR383656.12.
- chr16:46,469,341–46,698,394, 12 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6.
- chr21:10,482,738–13,120,807, 11 genes (within-gene range 0–1): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,507,764–49,508,806, 1 gene, copy number 9: AC119751.5.
- chr6:29,099,657–29,114,770, 2 genes, copy number 5–11: OR2J1, OR2J3.

Autosomal genes at a single copy (total copy number 1): 650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
